Somatic mutation profile of tumor specimen TCGA-A2-A0T1-01A (aliquot TCGA-A2-A0T1-01A-21D-A099-09) from TCGA case TCGA-A2-A0T1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.4 years (20,227 days).
Specimen TCGA-A2-A0T1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1322296-d871-4bbf-99ba-0b7b3474f91f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0T1-10A (Blood Derived Normal), aliquot TCGA-A2-A0T1-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02fca54a-159b-4069-8abe-4803a5a3df42

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs752691628, COSV99170465; called by muse, mutect2
- CHRNA5 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV100213858; called by muse, mutect2
- DLL1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.16); catalogued as rs372640222; called by muse, mutect2
- DOCK4 | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV70326997; called by muse, mutect2, varscan2
- EPHA6 | c.1720T>C p.Y574H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101061553; called by muse, mutect2
- EXO1 | c.2365A>T p.I789F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV100799683; called by muse, mutect2
- H2BC12 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as COSV63617612; called by muse, mutect2, varscan2
- HLTF | c.3000T>G p.I1000M | Missense Mutation (SNP) | VAF 122/427 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV56051410; called by muse, mutect2, varscan2
- INSIG2 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.983); catalogued as COSV55524001; called by muse, mutect2, varscan2
- LAPTM4B | c.671T>A p.I224K (on ENST00000445593; = p.I133K on NM_018407.6) | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101503488; called by muse, mutect2
- LSM12 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99518529; called by muse, mutect2
- LYST | c.5230G>T p.V1744F | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV101088814; called by muse, mutect2
- MEGF8 | c.3235C>T p.R1079C (on ENST00000251268 / NM_001271938.2; = p.R1012C on NM_001410.3) | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1252854271; called by muse, mutect2
- MLXIP | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs528028662, COSV59836738; called by muse, mutect2
- SPTAN1 | c.5509G>A p.G1837R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770133448, COSV63990121; called by muse, mutect2, varscan2
- TFE3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100252446; called by muse, mutect2
- TMPRSS15 | c.1656T>C p.C552= | Splice Region (SNP) | VAF 9/243 reads (4%) | catalogued as COSV99517426; called by muse, mutect2
- ZDHHC17 | c.1590G>T p.W530C | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100602051; called by muse, mutect2
- ZNF510 | c.1889G>T p.C630F | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99793807; called by muse, mutect2
- GSAP | c.1856dup p.L619Ffs*13 | Frame Shift Ins (INS) | VAF 26/260 reads (10%) | called by mutect2, pindel
- SPTB | c.1150del p.H384Tfs*5 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | called by mutect2, pindel, varscan2
- CACNA1C | c.3096C>T p.I1032= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs917266570, COSV59780101; called by muse, mutect2
- HROB | c.1017C>T p.P339= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV55371131; called by muse, mutect2, varscan2
- RPLP0 | c.304T>C p.L102= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs1307284497, COSV56115642; called by muse, mutect2, varscan2
- TOPORS | c.2157T>G p.S719= | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as COSV100859482; called by muse, mutect2
- ZNF142 | c.2118G>A p.R706= (on ENST00000411696 / NM_001379660.1; = p.R506= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV68746151; called by muse, mutect2, varscan2
